Gene-level copy-number profile of tumor specimen MP2PRT-PAPVNZ-TMP1-A from MP2PRT case MP2PRT-PAPVNZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,041 days).
Specimen MP2PRT-PAPVNZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 414e837c-e445-47b8-a199-35f55111ff61.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPVNZ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,252 have no estimate.
https://portal.gdc.cancer.gov/files/538ea8e1-ea85-4da1-848b-d76989539dab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 165; copy number 1: 967; copy number 2: 56,874; copy number 3: 365.

Homozygous deletions (total copy number 0; autosomes only): 165 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,861,886–89,027,731, 13 genes (within-gene range 0–1): IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11.
- chr2:89,078,010–89,085,787, 2 genes (within-gene range 0–1): IGKV2-14, IGKV3-15.
- chr2:89,234,174–89,310,144, 10 genes (within-gene range 0–1): IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr2:89,968,867–89,990,221, 3 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr7:38,257,879–38,311,808, 7 genes (within-gene range 0–1): TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–3): TRDD1, TRDD2.
- chr14:105,672,308–106,481,706, 126 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–2): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 967. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
